Somatic mutation profile of tumor specimen TCGA-VS-A959-01A (aliquot TCGA-VS-A959-01A-11D-A42O-09) from TCGA case TCGA-VS-A959, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 76.4 years (27,897 days).
Specimen TCGA-VS-A959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa771efb-8b97-43d5-a864-34a796968a8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A959-10A (Blood Derived Normal), aliquot TCGA-VS-A959-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/636728ee-c4b1-4435-a6ca-0cb7fe1b0bce

The open-access MAF lists 256 somatic variants for this specimen: 181 protein-altering or splice-affecting, 70 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 70, Nonsense Mutation 18, RNA 4, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- METTL14 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 19/187 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs377767332, CM016192, COSV100747444; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABRAXAS2 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100044797; called by mutect2, varscan2
- ACTB | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as rs1484491064, COSV59318696, COSV59320746; called by muse, mutect2, varscan2
- ADAM29 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV100821887; called by muse, mutect2, varscan2
- AFF2 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV54008837; called by muse, mutect2, varscan2
- AGMO | c.1194G>C p.L398F | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.569); catalogued as COSV100693469; called by muse, mutect2
- AGO3 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV99867878; called by muse, mutect2
- AHCY | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV99463933; called by muse, mutect2
- AHNAK2 | c.9066G>T p.K3022N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV100315240; called by muse, mutect2
- AOAH | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs150438169, COSV51737665; called by muse, mutect2, varscan2
- AP3B1 | c.2580C>T p.V860= | Splice Region (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99670541; called by muse, mutect2, varscan2
- AP4E1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99956209; called by muse, mutect2
- ASAP3 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100369412; called by muse, mutect2
- ASB10 | c.1366C>T p.R456C (on ENST00000420175 / NM_001142459.2; = p.R441C on NM_080871.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs776358265, COSV99318067; called by mutect2, varscan2
- ASH1L | c.5051G>A p.R1684Q | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.368); catalogued as rs1280114281, COSV100853070; called by muse, mutect2, varscan2
- ATF7IP | c.3731G>A p.R1244Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99661120; called by muse, mutect2
- ATG2B | c.412G>C p.D138H | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100737646; called by muse, mutect2
- ATXN3 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100515096; called by muse, mutect2, varscan2
- BBS5 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99751574; called by muse, mutect2, varscan2
- BIRC6 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1486003756, COSV101427761; called by muse, mutect2, varscan2
- BIRC6 | c.1787G>A p.R596K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV101427763; called by muse, mutect2, varscan2
- BLNK | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782566012, COSV56414279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1343341933; called by muse, mutect2
- BMP4 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1011657927, COSV99816713; called by muse, mutect2, varscan2
- BPTF | c.3173G>A p.R1058K | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100073869; called by muse, mutect2, varscan2
- BST2 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753915464, COSV53089546, COSV53089833; called by muse, mutect2, varscan2
- C10orf120 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577934787, COSV61492459; called by muse, mutect2, varscan2
- C11orf54 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs780612413, COSV100486932; called by muse, mutect2, varscan2
- C2orf16 | c.4691G>A p.R1564K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1422301359, COSV100820623, COSV62678024; called by muse, mutect2
- CCDC18 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.23); catalogued as COSV100159168, COSV100159918; called by muse, mutect2
- CD207 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV101338523; called by muse, mutect2
- CDC42BPA | c.4867G>C p.E1623Q (on ENST00000334218 / NM_001366019.2; = p.E1610Q on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.986); catalogued as COSV100503510; called by muse, mutect2
- CDH12 | c.488G>C p.G163A | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV101200910; called by muse, mutect2
- CDH13 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99221744, COSV99227491; called by muse, mutect2, varscan2
- CDH15 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1476971953; called by muse, mutect2
- CEBPZ | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99135388; called by muse, mutect2
- CEP43 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100835532; called by muse, mutect2
- CHD6 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58554075; called by muse, mutect2
- CHM | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100752970; called by muse, mutect2
- CNTNAP4 | c.2652C>A p.N884K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100269135; called by muse, mutect2, varscan2
- CR1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.356); catalogued as rs534091932, COSV65456666, COSV65459135, COSV65460002; called by muse, mutect2, varscan2
- CRYZ | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100558447; called by muse, mutect2
- CTBP1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52071859; called by muse, mutect2, varscan2
- CTSH | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99585328; called by muse, mutect2
- DCAF12L1 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64422350; called by muse, mutect2
- DCLK1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs770183177, COSV55172587, COSV55176126; called by muse, mutect2, varscan2
- DOCK3 | c.3332G>A p.R1111Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs746006994, COSV99808791, COSV99809076; called by muse, varscan2
- EDC4 | c.3047G>A p.G1016E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV100197410; called by muse, mutect2
- EIF4G3 | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV99942989; called by muse, mutect2, varscan2
- ELFN2 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101297460; called by muse, mutect2
- EMX2 | c.6C>A p.F2L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101463565, COSV71294676; called by muse, mutect2
- ENGASE | c.2185C>T p.Q729* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100285639; called by muse, mutect2, varscan2
- ERRFI1 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs772410037, COSV101087933; called by mutect2, varscan2
- EVC2 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100184864; called by muse, mutect2, varscan2
- FAM160B1 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100985135; called by muse, mutect2
- FANCD2 | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV99810184; called by muse, mutect2, varscan2
- FBXL18 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101212140; called by muse, mutect2
- FBXO30 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV99394945; called by muse, mutect2
- FPGT-TNNI3K | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV100435366; called by muse, mutect2
- GALNT6 | c.1326T>G p.I442M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); catalogued as COSV100695277; called by muse, mutect2
- GIT2 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100188760; called by muse, mutect2, varscan2
- GNE | c.1399C>G p.Q467E (on ENST00000396594 / NM_001128227.3; = p.Q436E on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as CM102239, COSV100929863; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT tolerated (0.19); catalogued as rs1408839832, COSV99081874; called by muse, mutect2
- GRB7 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100485345, COSV100485492; called by muse, mutect2, varscan2
- GRIA2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.366); catalogued as COSV99642748; called by muse, mutect2, varscan2
- GRK2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs768707526, COSV100419547; called by muse, mutect2, varscan2
- H2AC11 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV100345567; called by muse, mutect2
- H2BC14 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs1274587586, COSV100297464; called by muse, mutect2, varscan2
- HTR4 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100087046; called by muse, mutect2
- IFNL3 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 15/156 reads (10%) | catalogued as COSV69830025; called by muse, mutect2
- ISM2 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV99376403; called by muse, mutect2, varscan2
- JAK3 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs777849274, COSV71685924; called by muse, mutect2, varscan2
- KDM1B | c.90G>A p.A30= | Splice Region (SNP) | VAF 17/62 reads (27%) | catalogued as rs1397865170, COSV52813672; called by muse, mutect2, varscan2
- KDM3B | c.2429C>T p.S810L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1291356426, COSV100069094; called by muse, mutect2, varscan2
- KIF11 | c.2146C>T p.Q716* | Nonsense Mutation (SNP) | VAF 6/97 reads (6%) | catalogued as COSV99585605; called by muse, mutect2
- KLF12 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100888396; called by muse, mutect2, varscan2
- KLHL20 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV99268106; called by muse, mutect2
- KMT2D | c.7000C>T p.R2334W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1196495584, COSV99976981; ClinVar: uncertain significance; called by mutect2, varscan2
- KRT39 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100842157, COSV62916845; called by muse, mutect2, varscan2
- LCT | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV99928418; called by mutect2, varscan2
- LECT2 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV99191807; called by muse, mutect2, varscan2
- LMTK2 | c.3427G>A p.E1143K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs767583972, COSV99805868; called by muse, mutect2, varscan2
- LRRCC1 | c.3095T>C p.M1032T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV100835255; called by muse, mutect2, varscan2
- MAP3K4 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.341); catalogued as COSV100814988; called by muse, mutect2, varscan2
- MAP3K7CL | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV54507388, COSV99726328; called by muse, mutect2, varscan2
- MAP6 | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV100496398; called by muse, mutect2, varscan2
- METAP1D | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1389890370, COSV100249769; called by muse, varscan2
- MROH5 | c.92dup p.V32Cfs*70 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | catalogued as rs748849454; called by mutect2, varscan2
- MYO18A | c.3541G>A p.E1181K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100571870, COSV62863643; called by mutect2, varscan2
- NAV3 | c.3745C>T p.R1249* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as rs1461827869, COSV57070023; called by muse, mutect2
- NEK8 | c.558C>G p.I186M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.683); catalogued as COSV99261440; called by muse, mutect2, varscan2
- NKX2-1 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.304); catalogued as rs548436641, COSV100701732; called by muse, mutect2
- NXF1 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV99585684; called by muse, mutect2, varscan2
- ODF2 | c.378G>T p.K126N (on ENST00000434106 / NM_153433.2; = p.K102N on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100654379; called by muse, mutect2
- OGFOD1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100272881; called by muse, mutect2
- OR4K5 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as rs1190158974, COSV100262103; called by muse, mutect2
- OR5B21 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); catalogued as COSV100835082, COSV100835114, COSV64482300; called by muse, mutect2
- OR5H14 | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV101454056, COSV71193871; called by muse, mutect2
- PCDHA6 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100971202; called by muse, mutect2
- PCLO | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100426761; called by muse, mutect2, varscan2
- PDE1C | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100370673, COSV100372003; called by muse, mutect2, varscan2
- PFKFB2 | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | PolyPhen probably damaging (0.952); catalogued as rs955937201, COSV100891836; called by muse, mutect2, varscan2
- PHF11 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as COSV100710509; called by muse, mutect2, varscan2
- PHF12 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99255401; called by muse, mutect2, varscan2
- PIK3C2G | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.085); catalogued as COSV99849046; called by muse, mutect2
- PKD1L1 | c.5189G>A p.R1730K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV99218191; called by muse, mutect2, varscan2
- PLEKHA4 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 9/111 reads (8%) | catalogued as COSV99611999; called by muse, mutect2
- PPFIA2 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1204864624, COSV100331418; called by muse, mutect2
- PPFIA3 | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100494649; called by muse, mutect2
- PRKX | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs770062921, COSV53326285, COSV99467520; called by muse, mutect2, varscan2
- PRR23B | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.234); catalogued as COSV61494310; called by muse, mutect2, varscan2
- PSG5 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV100742538; called by muse, mutect2
- PSG5 | c.79T>C p.F27L | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV100742539; called by muse, mutect2
- PTPRO | c.3631G>A p.E1211K (on ENST00000281171 / NM_030667.3; = p.E1183K on NM_002848.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746890263, COSV99839481; called by mutect2, varscan2
- RAB3D | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144435530; called by muse, mutect2, varscan2
- RAI1 | c.5560G>C p.D1854H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV99883195; called by muse, mutect2, varscan2
- RASIP1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV55803467, COSV99710428, COSV99711072; called by muse, mutect2
- RNF123 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100570138; called by muse, mutect2, varscan2
- RTN2 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs199848753, COSV55596038; called by muse, mutect2, varscan2
- RUBCN | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99583035; called by muse, mutect2
- RYR1 | c.6483G>C p.Q2161H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100614237; called by muse, mutect2
- SACS | c.7303C>T p.L2435F | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV101207143, COSV66533118; called by muse, mutect2
- SACS | c.4844del p.P1615Lfs*8 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as COSV66535787; called by mutect2, pindel, varscan2
- SCAI | c.823C>A p.L275M (on ENST00000336505 / NM_001144877.3; = p.L298M on NM_173690.5) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100332132, COSV60617654; called by muse, mutect2
- SCN7A | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101313062, COSV101313364; called by muse, mutect2
- SH2D3A | c.980A>T p.Q327L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV99837766; called by muse, mutect2
- SH3RF1 | c.1649G>A p.G550E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.502); catalogued as COSV99498572; called by muse, mutect2, varscan2
- SHISAL1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs772497929, COSV66987863; called by muse, mutect2, varscan2
- SIPA1L1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100665052; called by muse, mutect2
- SIPA1L3 | c.4039G>A p.G1347S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as rs766968887, COSV55915771, COSV99727049; called by muse, mutect2, varscan2
- SLC15A1 | c.978G>C p.Q326H | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100919412; called by muse, mutect2
- SLC25A20 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100033556; called by muse, mutect2, varscan2
- SOCS2 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225826658, COSV61392330; called by muse, mutect2, varscan2
- SPAG6 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs779459381, COSV57619778; called by mutect2, varscan2
- SPI1 | c.143-1G>A p.X48_splice | Splice Site (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99908627; called by muse, mutect2
- SPOPL | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV99699273; called by muse, mutect2
- SPTA1 | c.4068C>G p.I1356M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV100934109, COSV100934758, COSV63749559; called by muse, mutect2
- STRBP | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100724056; called by muse, mutect2, varscan2
- STYXL2 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV99608485; called by muse, mutect2
- TCF20 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs375607848; called by muse, mutect2
- TCP11L1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1441435959, COSV100177759; called by muse, mutect2
- TET1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV65384402; called by muse, mutect2, varscan2
- TLR2 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV99472041; called by muse, mutect2, varscan2
- TMEM230 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99176941; called by muse, mutect2, varscan2
- TMOD1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99403683; called by muse, mutect2
- TNPO3 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.115); catalogued as rs1433633369, COSV99602361; called by muse, mutect2
- TOGARAM1 | c.4510C>T p.R1504C | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752360247, COSV63892831; called by muse, mutect2, varscan2
- TRDN | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV100520666, COSV100523373; called by muse, mutect2, varscan2
- TRIM54 | c.994G>A p.A332T (on ENST00000380075 / NM_187841.3; = p.A374T on NM_032546.4) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs772619318, COSV99274132; called by muse, mutect2, varscan2
- TTN | c.43361G>A p.R14454Q (on ENST00000591111; = p.R7030Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | PolyPhen possibly damaging (0.889); catalogued as rs369453963, COSV60185548; called by muse, mutect2, varscan2
- TTN | c.33289G>A p.E11097K (on ENST00000591111; = p.E10170K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | PolyPhen benign (0); catalogued as rs748080418, COSV100591886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.29800G>A p.E9934K (on ENST00000591111; = p.E9007K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | PolyPhen benign (0); catalogued as COSV100591888; called by muse, mutect2
- TUBAL3 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100990436; called by muse, mutect2
- USP25 | c.1119A>T p.E373D | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99583041; called by muse, mutect2
- USP34 | c.7192G>C p.E2398Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.38); catalogued as COSV101276570; called by muse, mutect2, varscan2
- VCP | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100734070; called by muse, mutect2, varscan2
- VPS18 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99592235; called by muse, mutect2
- VWA3A | c.1198T>C p.F400L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV100240517; called by muse, mutect2
- WDR12 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99650888, COSV99651107; called by muse, mutect2, varscan2
- ZNF12 | c.589G>A p.E197K (on ENST00000405858 / NM_016265.4; = p.E159K on NM_006956.3) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100703545; called by muse, mutect2
- ZNF33A | c.965A>G p.D322G (on ENST00000458705 / NM_006974.3; = p.D323G on NM_006954.2) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.049); catalogued as rs1305915058, COSV100275464; called by muse, mutect2, varscan2
- ZNF557 | c.1247C>T p.T416M (on ENST00000414706 / NM_001044388.2; = p.T423M on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs747902079, COSV53273523; called by muse, mutect2, varscan2
- ZNF600 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 14/154 reads (9%) | catalogued as COSV100592885, COSV100592917; called by muse, mutect2
- ZNF600 | c.1040G>C p.R347T | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.394); catalogued as COSV100592886; called by muse, mutect2, varscan2
- ZNF600 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.074); catalogued as COSV100592889; called by muse, mutect2, varscan2
- ZNF668 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1331091014, COSV100336293; called by muse, mutect2, varscan2
- ZNF69 | c.487C>T p.P163S (on ENST00000429654 / NM_001364730.1; = p.P149S on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as COSV100420849; called by muse, mutect2, varscan2
- ZNF75A | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 5/55 reads (9%) | catalogued as COSV101556595, COSV73039563; called by muse, mutect2
- ZRANB2 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV54674726; called by muse, mutect2
- AS3MT | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- CCL4L2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2
- GRXCR1 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PTPRF | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.257); called by muse, mutect2
- SAMD14 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- TG | c.6815C>T p.S2272F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, mutect2
- TP53INP1 | c.26_29del p.F9Wfs*28 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- UBR5 | c.6547G>A p.D2183N | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.117); called by muse, mutect2
- ADAMTS4 | c.1359C>T p.F453= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs1350748581, COSV63491400; called by muse, mutect2
- AHR | c.1920G>A p.Q640= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99619168; called by muse, mutect2, varscan2
- APOB | c.10776T>A p.S3592= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99263255; called by muse, mutect2
- ASPM | c.7188G>A p.R2396= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1376267459, COSV99659386; called by muse, mutect2, varscan2
- ATP2C2 | c.933C>T p.L311= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99297392; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1356G>A p.L452= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV99230365; called by muse, mutect2
- BLM | c.819G>A p.K273= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV100756863, COSV100756893; called by muse, mutect2, varscan2
- CD163 | c.1767G>A p.K589= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100775599; called by muse, mutect2, varscan2
- CDC14B | c.972G>A p.L324= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99685102; called by muse, mutect2, varscan2
- CDH12 | c.267G>A p.V89= | Silent (SNP) | VAF 22/272 reads (8%) | catalogued as COSV66404600; called by muse, mutect2
- CHAF1B | c.522C>T p.V174= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100023313; called by muse, mutect2, varscan2
- CLBA1 | c.432C>G p.L144= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101120951; called by muse, mutect2, varscan2
- CST4 | c.402G>A p.V134= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV54149679; called by muse, mutect2
- CTTNBP2 | c.2889G>A p.E963= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99352833; called by muse, mutect2, varscan2
- DFFA | c.366G>A p.L122= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100986611; called by muse, mutect2, varscan2
- DGKZ | c.276C>T p.L92= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100550956; called by muse, mutect2, varscan2
- DNAH8 | c.741C>T p.L247= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV59462618; called by muse, mutect2
- EEF2KMT | c.198C>T p.S66= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- ELMOD1 | c.912G>A p.E304= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99759605; called by muse, mutect2, varscan2
- EXOC3 | c.726G>A p.K242= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100155370, COSV59268966; called by mutect2, varscan2
- FANCD2 | c.2835C>T p.I945= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99810187; called by muse, mutect2, varscan2
- FAT4 | c.5493C>T p.V1831= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100627117; called by muse, mutect2
- FILIP1 | c.96C>T p.L32= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1374101521, COSV99383697; called by muse, mutect2, varscan2
- GDPD5 | c.654C>T p.I218= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100409021; called by muse, mutect2, varscan2
- GK5 | c.291G>A p.Q97= | Silent (SNP) | VAF 11/134 reads (8%) | catalogued as COSV101242059; called by muse, mutect2
- GNE | c.2094C>T p.L698= (on ENST00000396594 / NM_001128227.3; = p.L667= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100929860; called by muse, mutect2
- HCN1 | c.789C>T p.L263= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs1359320329, COSV100298128; called by muse, mutect2, varscan2
- HEPH | c.1635C>T p.P545= (on ENST00000343002; = p.P278= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100293970; called by muse, mutect2
- HIF1A | c.2121T>C p.N707= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV60190827; called by muse, mutect2
- HIP1R | c.2928G>A p.L976= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99458121; called by muse, mutect2, varscan2
- HSPG2 | c.1191G>A p.R397= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV101012859; called by muse, mutect2
- KRCC1 | c.288G>A p.L96= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100712794; called by muse, mutect2
- LRP1B | c.9996C>T p.F3332= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV101251241; called by muse, mutect2
- LVRN | c.810T>C p.Y270= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100773300; called by muse, mutect2, varscan2
- MAP7D1 | c.2478C>T p.F826= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs773212376, COSV60217679; called by muse, mutect2
- MED12 | c.4770C>T p.I1590= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100375687; called by muse, mutect2
- MYH1 | c.1578C>G p.L526= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99874734; called by muse, mutect2
- MYLK2 | c.1731C>T p.S577= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs772804572, COSV65658960; called by mutect2, varscan2
- MYO16 | c.3900A>G p.P1300= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV100695291; called by muse, mutect2
- NEK3 | c.636C>T p.L212= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99317406, COSV99317434; called by muse, mutect2
- NSMCE3 | c.666C>T p.L222= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV54290577; called by muse, mutect2
- OGFR | c.1830A>G p.A610= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs762864108, COSV99283623; called by muse, varscan2
- PCBP2 | c.15G>A p.V5= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100827431; called by muse, mutect2
- PKD2L1 | c.1362C>T p.F454= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100559268; called by mutect2, varscan2
- PLB1 | c.501C>T p.I167= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV100577443; called by muse, mutect2
- RAD50 | c.747T>C p.D249= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99528513; called by muse, mutect2, varscan2
- RADX | c.69G>A p.E23= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV100998727; called by muse, mutect2
- RAI1 | c.3618C>T p.P1206= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- RNF148 | c.384C>T p.I128= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100411413; called by muse, mutect2, varscan2
- RTTN | c.5148C>T p.I1716= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99730770; called by muse, mutect2
- SEC24D | c.1497G>A p.V499= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV99755297; called by muse, mutect2, varscan2
- SGCZ | c.298C>T p.L100= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV101166470; called by muse, mutect2, varscan2
- SI | c.1275C>T p.I425= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV100013656; called by muse, mutect2, varscan2
- SLAIN1 | c.1665C>T p.L555= (on ENST00000466548; = p.L292= on NM_144595.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV57388169; called by muse, mutect2
- SMG1 | c.4131C>T p.L1377= | Silent (SNP) | VAF 38/303 reads (13%) | catalogued as rs1287665462, COSV101245026; called by muse, mutect2, varscan2
- SORCS1 | c.2889C>A p.I963= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV53905374, COSV99542613; called by muse, mutect2, varscan2
- SPATA20 | c.744C>T p.F248= (on ENST00000356488 / NM_001258372.1; = p.F264= on NM_022827.4) | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- SPATA31D1 | c.3822C>A p.V1274= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1263955267, COSV100782432; called by muse, mutect2, varscan2
- STAM | c.1243C>T p.L415= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV66352483; called by mutect2, varscan2
- TARS2 | c.2127G>A p.T709= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs774814779, COSV100681594; called by muse, mutect2
- TBC1D4 | c.1311C>T p.F437= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100884507; called by muse, mutect2, varscan2
- TENM1 | c.4284G>A p.A1428= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1159993412, COSV64436976; called by muse, mutect2, varscan2
- THSD7B | c.1356G>A p.L452= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99743237; called by muse, mutect2
- TJP1 | c.327G>A p.K109= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as rs1025200343, COSV62041884; called by muse, mutect2
- TOMM40 | c.618G>A p.G206= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV99374733; called by muse, varscan2
- TRGJ1 | c.21C>G p.L7= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2, varscan2
- UGT1A8 | c.240A>G p.S80= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs1191514168, COSV100990104; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1080C>T p.F360= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV99511372; called by muse, mutect2
- WASHC2C | c.936A>G p.L312= | Silent (SNP) | VAF 14/285 reads (5%) | called by muse, mutect2
- ZNF331 | c.1026C>T p.L342= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs200192910, COSV99466780; called by muse, mutect2, varscan2
- SLC22A17 | n.1540G>A | RNA (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99248458; called by muse, mutect2
- SNORD116-3 | n.84G>A | RNA (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- SSPOP | n.13081G>A | RNA (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100946946; called by muse, mutect2, varscan2
- STAG3L2 | n.386A>T | RNA (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2156G>A | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100313571; called by muse, mutect2
